Somatic mutation profile of tumor specimen MMRF_2518_1_BM_CD138pos (aliquot MMRF_2518_1_BM_CD138pos_T1_KHS5U_L13280) from MMRF case MMRF_2518, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 85.1 years (31,093 days).
Specimen MMRF_2518_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2b939f5-4ec9-421c-962f-163fa9066dcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2518_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2518_1_PB_WBC_C3_KHS5U_L13281; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fe2b8c5-ca80-4b64-8781-0017476e7bf3

The open-access MAF lists 144 somatic variants for this specimen: 64 protein-altering or splice-affecting, 20 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, 3'UTR 29, Silent 20, Intron 19, 5'UTR 4, RNA 4, 5'Flank 3, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSS1 | c.410-5G>A | Splice Region (SNP) | VAF 48/120 reads (40%) | catalogued as rs750406939; called by muse, mutect2, varscan2
- AXDND1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs753955745; called by muse, mutect2, varscan2
- CDH10 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52572589, COSV52591075; called by muse, mutect2, varscan2
- COL26A1 | c.944C>T p.P315L (on ENST00000313669 / NM_001278563.3; = p.P313L on NM_133457.4) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs541739687; called by muse, mutect2, varscan2
- DNM2 | c.1564C>T p.R522C (on ENST00000355667 / NM_001005360.3; = p.R518C on NM_004945.3) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as CM123662; called by muse, mutect2, varscan2
- EIF2AK3 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs932283418; called by muse, mutect2
- FSCN3 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 124/260 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs747805055, COSV50000279, COSV50000925; called by muse, mutect2, varscan2
- IGLV3-1 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs374018767; called by muse, varscan2
- KIF4B | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775915028, COSV70528329; called by muse, mutect2, varscan2
- MAP6 | c.1080A>G p.I360M | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1027692867; called by muse, mutect2
- MSH2 | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs755501968; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MYRFL | c.2215C>T p.R739* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as rs180790706; called by muse, mutect2, varscan2
- OBSL1 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1316854085; called by muse, mutect2, varscan2
- PALLD | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs1409360651, COSV54990978; called by muse, mutect2, varscan2
- PCDHA8 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs140143048; called by mutect2, varscan2
- PIK3AP1 | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754633544, COSV59537311; called by muse, mutect2, varscan2
- PIK3R2 | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746939639; called by muse, mutect2, varscan2
- PITPNM3 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs150769456; called by muse, mutect2, varscan2
- PTPRT | c.1109C>T p.T370M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs760520624, COSV61981487; called by muse, mutect2, varscan2
- SCUBE1 | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140515412; called by muse, mutect2, varscan2
- SDK1 | c.4424-1G>T p.X1475_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV67368513; called by muse, mutect2, varscan2
- SDK2 | c.5998G>A p.V2000I | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as rs375316369; called by muse, mutect2, varscan2
- SEPSECS | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754992211; called by muse, mutect2, varscan2
- TBXA2R | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs377392586; called by muse, mutect2, varscan2
- TRIM29 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 107/252 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs948449592; called by muse, mutect2, varscan2
- TSPAN13 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as rs1165836721; called by muse, mutect2, varscan2
- VWCE | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 64/420 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283991632; called by muse, mutect2, varscan2
- WDR91 | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs1443804368; called by muse, mutect2, varscan2
- ZNF280C | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1444015463, COSV63968830; called by muse, mutect2, varscan2
- ZNF880 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.737); catalogued as rs879095094; called by muse, mutect2, varscan2
- AC090517.4 | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACACA | c.1343T>C p.L448P | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CAPN7 | c.766A>C p.T256P | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, varscan2
- CDC73 | c.31T>C p.Y11H | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- DNAH2 | c.1453G>A p.V485M | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- DNAH5 | c.7820A>T p.Y2607F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EEF1A1 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- EPS15L1 | c.1073T>C p.M358T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM149B1 | c.137A>C p.D46A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FGF3 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FRY | c.3016C>A p.H1006N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRAMD2B | c.519A>G p.I173M | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HIP1R | c.2103T>A p.D701E | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- HKDC1 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPUL2 | c.543T>A p.D181E | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IL16 | c.2163C>G p.I721M (on ENST00000302987 / NM_172217.5; = p.I20M on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 219/554 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ITGA1 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2
- KBTBD13 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- LARGE1 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OR10G4 | c.817A>G p.I273V | Missense Mutation (SNP) | VAF 46/431 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCSK2 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PLOD2 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PLXNA2 | c.1102A>C p.K368Q | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- RGS9 | c.459T>G p.Y153* | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
- SDCCAG8 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEPTIN4 | c.1378T>C p.S460P | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SIAH2 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRAPPC3L | c.426+2T>A p.X142_splice | Splice Site (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- UCK1 | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC79 | c.4990G>A p.A1664T (on ENST00000393151 / NM_001346218.2; = p.A1487T on NM_020818.5) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WWC1 | c.2725A>G p.R909G | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- XIRP2 | c.1010dup p.N337Kfs*9 (on ENST00000628543; = p.N512Kfs*9 on NM_152381.6) | Frame Shift Ins (INS) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- XKR5 | c.944A>G p.Y315C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZNF257 | c.1163C>A p.T388N | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ASPRV1 | c.264C>T p.S88= | Silent (SNP) | VAF 84/213 reads (39%) | catalogued as rs150248741, COSV100208438; called by muse, mutect2, varscan2
- BMP3 | c.822T>C p.D274= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs758894719; called by muse, mutect2, varscan2
- CNTRL | c.6172C>T p.L2058= | Silent (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- GRIN3B | c.2898C>T p.Y966= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1420492104; called by muse, mutect2
- IGLL5 | c.78G>A p.L26= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs551962377, COSV73250938; called by muse, mutect2, varscan2
- IGLV3-1 | c.6A>G p.A2= | Silent (SNP) | VAF 47/191 reads (25%) | called by muse, mutect2, varscan2
- KCP | c.2703G>A p.G901= (on ENST00000620378; = p.G961= on NM_001366122.1) | Silent (SNP) | VAF 58/112 reads (52%) | catalogued as COSV52824063; called by muse, mutect2, varscan2
- KIAA1614 | c.2652C>T p.S884= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as rs1242041800, COSV62550774; called by muse, mutect2
- KRT83 | c.948C>T p.H316= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as rs748796258, COSV53342275; called by muse, mutect2, varscan2
- KRTAP10-6 | c.78C>T p.D26= | Silent (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2
- MED24 | c.2541C>T p.F847= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as rs746879172, COSV56641470; called by muse, mutect2, varscan2
- MUC22 | c.1980C>T p.I660= | Silent (SNP) | VAF 139/247 reads (56%) | called by muse, mutect2, varscan2
- MYO18B | c.1212C>T p.N404= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs772481621; called by muse, mutect2, varscan2
- NGFR | c.468C>T p.D156= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as rs980651699; called by muse, mutect2, varscan2
- PDK1 | c.1161C>A p.I387= | Silent (SNP) | VAF 51/145 reads (35%) | called by muse, mutect2, varscan2
- PKD2 | c.2583C>T p.D861= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs369520452; called by muse, mutect2, varscan2
- RPS6KA6 | c.825T>C p.G275= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- SHC3 | c.117G>A p.A39= | Silent (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- SYT9 | c.864G>A p.V288= | Silent (SNP) | VAF 129/222 reads (58%) | catalogued as rs755721804, COSV59616865; called by muse, mutect2, varscan2
- ZBTB8B | c.138C>T p.S46= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as rs1005884993; called by muse, mutect2, varscan2
- ADAMTS5 | c.*4888C>A | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2
- AK2 | c.299+1431A>C | Intron (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- AL356585.2 | n.968A>G | RNA (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- ANXA4 | c.*748A>T | 3'UTR (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021449 A>G | 5'Flank (SNP) | VAF 38/120 reads (32%) | catalogued as COSV104379276, COSV55850504; called by muse, mutect2, varscan2
- BRWD1 | c.6571+853del | Intron (DEL) | VAF 46/103 reads (45%) | catalogued as rs1198447688; called by mutect2, pindel, varscan2
- C1orf43 | c.*337_*340del | 3'UTR (DEL) | VAF 14/68 reads (21%) | called by pindel, varscan2
- CCDC150 | c.576+20G>A | Intron (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- CCND2 | c.*1653T>A | 3'UTR (SNP) | VAF 9/38 reads (24%) | catalogued as rs942815958; called by muse, mutect2, varscan2
- CCPG1 | c.455-957T>C | Intron (SNP) | VAF 39/251 reads (16%) | catalogued as rs760615166; called by muse, mutect2, varscan2
- CISH | c.*730_*737del | 3'UTR (DEL) | VAF 27/156 reads (17%) | called by mutect2, pindel, varscan2
- COG5 | c.2312+2629T>C | Intron (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- CRAMP1 | c.*1337C>G | 3'UTR (SNP) | VAF 73/238 reads (31%) | catalogued as rs1320470025; called by muse, mutect2, varscan2
- DAZL | c.3+740C>T | Intron (SNP) | VAF 37/137 reads (27%) | called by muse, mutect2, varscan2
- DENND5A | c.*132G>T | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- EBNA1BP2 | c.-111G>A | 5'UTR (SNP) | VAF 97/357 reads (27%) | called by muse, mutect2, varscan2
- EIF4E | c.*6328del | 3'UTR (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- EPB41L4B | c.*1704dup | 3'UTR (INS) | VAF 22/53 reads (42%) | called by mutect2, varscan2
- FOXL1 | c.*145G>A | 3'UTR (SNP) | VAF 39/107 reads (36%) | called by muse, mutect2, varscan2
- GABRA5 | c.87-295G>C | Intron (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- GABRG2 | c.1249-1427del | Intron (DEL) | VAF 17/45 reads (38%) | catalogued as rs912927082; called by mutect2, varscan2
- GRM7 | c.1034-11955A>T | Intron (SNP) | VAF 70/311 reads (23%) | called by muse, mutect2, varscan2
- HES2 | c.*1529G>A | 3'UTR (SNP) | VAF 74/186 reads (40%) | called by muse, mutect2, varscan2
- HIF1AN | c.*287T>G | 3'UTR (SNP) | VAF 49/153 reads (32%) | catalogued as COSV100142686; called by muse, mutect2, varscan2
- HNRNPH1 | c.1300+30T>C | Intron (SNP) | VAF 60/165 reads (36%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.*352A>T | 3'UTR (SNP) | VAF 26/115 reads (23%) | catalogued as rs1239547240; called by muse, mutect2, varscan2
- LINC02551 | n.1237C>T | RNA (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- LINC02873 | n.3096G>T | RNA (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2
- LYPD1 | c.-16C>T | 5'UTR (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2
- MITF | c.352-1076T>C | Intron (SNP) | VAF 45/193 reads (23%) | called by muse, mutect2, varscan2
- NPAT | c.*320C>T | 3'UTR (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- NTRK3 | c.*6071T>A | 3'UTR (SNP) | VAF 41/110 reads (37%) | called by muse, mutect2, varscan2
- NUDT16 | c.*408del | 3'UTR (DEL) | VAF 43/204 reads (21%) | called by mutect2, pindel, varscan2
- ODC1 | c.*236C>T | 3'UTR (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- OPCML | c.*2856C>A | 3'UTR (SNP) | VAF 34/126 reads (27%) | catalogued as rs751535203; called by muse, mutect2, varscan2
- OR52A1 | c.-150A>G | 5'UTR (SNP) | VAF 55/83 reads (66%) | called by muse, mutect2, varscan2
- PDCD1 | c.*1065G>A | 3'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- PHYHIPL | c.107-27535T>G | Intron (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100874233; called by muse, mutect2, varscan2
- PIK3C3 | c.2189-24T>G | Intron (SNP) | VAF 38/132 reads (29%) | called by muse, varscan2
- PIKFYVE | c.*342G>A | 3'UTR (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- POU4F2 | c.-168_-167insT | 5'UTR (INS) | VAF 18/132 reads (14%) | called by mutect2, pindel, varscan2
- PTGR1 | c.651+1674T>C | Intron (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- RBM5 | c.*494A>G | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- RHOBTB1 | c.*225A>C | 3'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- RIMS1 | c.1679-16538C>G | Intron (SNP) | VAF 39/131 reads (30%) | catalogued as COSV53458156; called by muse, mutect2, varscan2
- RNF170 | c.*1460T>A | 3'UTR (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- RPS11 | chr19:49496428 C>T | 5'Flank (SNP) | VAF 89/181 reads (49%) | catalogued as rs200400398; called by muse, mutect2, varscan2
- RTN3 | c.*1395T>G | 3'UTR (SNP) | VAF 115/398 reads (29%) | called by muse, mutect2, varscan2
- SEMA3A | c.*1213A>C | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- SETD2 | c.4454+478A>G | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, varscan2
- SLC4A4 | c.1903+343A>T | Intron (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- SPTB | c.6602+1290C>T | Intron (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- STRADA | c.36+96C>T | Intron (SNP) | VAF 44/122 reads (36%) | catalogued as rs747348403; called by muse, mutect2, varscan2
- SYNGAP1 | c.*914A>T | 3'UTR (SNP) | VAF 37/132 reads (28%) | called by muse, mutect2, varscan2
- SYT7 | c.*3007G>A | 3'UTR (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- TIAL1 | chr10:119574932 T>C | 3'Flank (SNP) | VAF 17/50 reads (34%) | catalogued as rs955965576; called by muse, mutect2, varscan2
- TMEM202 | chr15:72398303 G>A | 5'Flank (SNP) | VAF 11/40 reads (28%) | catalogued as rs1190040447; called by muse, mutect2, varscan2
- TRIM6 | c.*397C>T | 3'UTR (SNP) | VAF 4/10 reads (40%) | catalogued as rs542072429; called by muse, mutect2
- VTI1A | c.*102G>C | 3'UTR (SNP) | VAF 53/206 reads (26%) | called by muse, mutect2, varscan2
- VWFP1 | n.426C>T | RNA (SNP) | VAF 12/40 reads (30%) | catalogued as rs1475751159; called by muse, mutect2, varscan2
